Surgical pathology report (de-identified scan), TCGA case TCGA-66-2768, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Indivumed, specimen TCGA-66-2768-01A (Primary Tumor).

[page 1 of 2]
Material examined:

Left lung, among others

Clinical diagnosis and question

Bronchial carcinoma of left lower lobe, histologically squamous cell carcinoma.

REPORT ON FINDINGS**Macroscopy**

- 1.) After attempted inflation of left lung at the deformed base measuring 10 x 8.5 cm and up to 21 cm in length, central bronchus resection plane located 3.5 cm proximal to the bifurcation of the upper lobe bronchus. Pleural fissure shows a strand of obliteration. Over segment 6 and adjacent sections of S10, an area of parietal pleura measuring 16 x 14 cm is extensively adhesive in parts and loosely attached in parts. Dorsal, lateral and basal pleura over segment 10 and adjacent sections of S9 show grayish-white discoloration and thickening in the region of the pleural margin. Main bronchus largely skeletonized. At the hilus are four lesioned grayish-black nodes between 0.3 and 0.8 cm in size. Lower lobe bronchus starting barely 1 cm distal to the ostium and proximal parts of the lower lobe segmental bronchi, especially of the basal group, show high-grade constriction or obstruction by a central soft to moderately firm, pale brown to whitish, predominantly endobronchial tumor, max. 6 cm in size, in the lower lobe, with relatively clear demarcation against the parenchyma, extending to within 0.3 cm of the hilar resection surface. Involvement of numerous grayish-black nodes up to 1 cm in size by the tumor. Constriction and partly pouch-like puckering of central blood vessels by the tumor. Focal extension to the pleural fissure, upper lobe shows no macroscopic infiltration. Peripheral branches of bronchi of the basal group are markedly dilated and filled with thick mucus. Basal lower lobe parenchyma incompletely folded, showing diffuse induration and patchy sections of brownish-yellow color, basal pleura over segment 9 questionably retracted. Rest of parenchyma and pleura show marked patchy or reticulate blackish pigmentation. At the bifurcation of the upper lobe bronchus two grayish-black nodes of 1 cm each, and subpleural grayish-black node of 0.3 cm in segment 4.
- 2.) Pleura left: two flat or membranous pieces of tissue measuring 4.8 x 2.5 and 3.5 x 2 cm, and up to 0.2 cm thick. Surfaces partly turbid or roughened.
- 3.) Interlobar LN (station 11) left: 1 cm lesioned grayish-black node or node part.
- 4.) Hilar LN (station 10) left: 1.2 cm node part with some surrounding tissue.
- 5.) Pulmonary ligament LN (station 9) left: 1.5 cm node part with some surrounding tissue.
- 6.) Paraesophageal LN (station 8) left: 1 cm fatty tissue without focal findings.
- 7.) Subcarinal LN (station 7): 1.5 cm node part.
- 8.) Paraaortic LN (station 6): 0.8 cm lesioned blackish node.
- 9.) Subaortic LN (aortopulmonary window) (station 5): 0.9 cm lesioned node or node part.
- 10.) Low paratracheal LN (station 4) left: 1 cm lesioned node or node part.
- 11.) Hilar LN (station 10) right: 1.1 cm lesioned node or node part.

[page 2 of 2]
Examined:

- 1.) Tumor with rest of parenchyma, with lower lobe bronchus, 2 sections with resection surface (color-marked), with pleural fissure, S10 peripheral, S9 basal, S6 with pleural adhesion + subpleural node S4, node at bronchial bifurcation. (halved in each case), central bronchus resection plane and resection margins of vessels, hilar nodes,
- 2.) 5 sections,
- 3.) - 11.) All material (in 4., 5. + 9. halved in each case, in 7. multi-segmented),
19 blocks, partly Elastica-van Gieson, PAS, diastase-PAS.

Microscopy

Description of histological and cytological findings omitted for capacity reasons.

EVALUATION

Primary diagnosis/diagnoses:

Central bronchopulmonary, histologically very poorly differentiated or largely undifferentiated, large-cell and polymorphocellular squamous cell carcinoma of the lower lobe of the left lung. TNM classification according to this picture pT2 pN1 V1 R0, stage IIB. C 34.3; M 8070/3. G4.

Secondary diagnosis/diagnoses:

Retrostenotic bronchiectasis and sections of massive, partly purulent peripheral bronchiolitis and smoldering, resorptive and organizing pneumonia in the lower lobe. Peripheral necrosis of the parenchyma in S9 with fibrin insudation into the pleura or pleural pockets and pleural fibrin exudation. In some cases massive clusters of brown pigmented alveolar macrophages. Rather slight anthracotic pigment deposits in the lung parenchyma. Isolated slight fibrosis of alveolar septa in S6 under a pleural adhesion zone. Slight reactive chronic parietal pleuritis (sample 2.)). Lymph nodes in some cases with only medium-grade anthracotic pigment deposits and in other cases with minimal anthracotic pigment deposits and reactive follicular hyperplasia.

Remark/addendum:

The squamous cell differentiation of the large-cell solid carcinoma is only shown in the form of the occasional detection of intercellular bridges and dyskeratotic cells. What is striking is the presence of numerous vacuolized tumor cells without seeing a mucin inclusion (lipid deposit?). The carcinoma shows obstructive endobronchial growth into the main bronchus of the lower lobe. The lymph node metastases only affect the lymph nodes located in the tumor area. Vascular invasion are seen not only in the small pulmonary vessels in the tumor, but also in a small and medium-sized vein within the adjacent mediastinal fatty tissue next to the main bronchus of the lower lobe.

Source: NCI Genomic Data Commons file 6f94cf65-3be9-40ec-9c39-73ce91f20789 (TCGA-66-2768.EBD0C8A9-A96A-4E09-8498-3476D1FAF292.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).